TCGA case TCGA-BP-4771 — Kidney Renal Clear Cell Carcinoma (TCGA-KIRC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney; Tissue source site: MSKCC. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/31201e73-a922-4acd-b859-fa2f9ba0af93

Demographics
Sex at birth: male; Race: white; Age at index: 62 years; Vital status: Dead; Days to death: 162 days.

Diagnoses (3)
1. Clear cell adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8310/3; ICD-10 code: C64.9; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 62.3 years (22,771 days); Year of diagnosis: 2005; AJCC pathologic T: T3a; AJCC pathologic N: N0; AJCC pathologic M: M1; AJCC pathologic stage: Stage IV; Tumor grade: G4; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: Yes.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 5.
   Treatment given: Treatment type: Radiation, External Beam; Initial disease status: Progressive Disease; Days to treatment start: -72 days; Days to treatment end: -50 days; Treatment dose: 3,750 cGy; Course number: 1; Number of fractions: 15; Treatment anatomic sites: Distant Site.
   Treatment given: Treatment type: Radiation, Intensity-Modulated Radiotherapy; Initial disease status: Recurrent Disease; Days to treatment start: 69 days; Days to treatment end: 73 days; Treatment dose: 2,000 cGy; Course number: 2; Number of fractions: 5; Treatment anatomic sites: Distant Site.
2. Metastasis of diagnosis 1 (Clear cell adenocarcinoma, NOS). Age at diagnosis: 62.4 years (22,794 days); Days to diagnosis: 23 days; Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 29 days; Treatment anatomic sites: Distant Site.
   Treatment given: Treatment type: Radiation Therapy, NOS.
   Recorded as not given: Pharmaceutical Therapy, NOS; Surgery, NOS to Locoregional Site.
3. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 62.6 years (22,881 days); Days to diagnosis: 110 days; Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS; Surgery, NOS to Distant Site; Surgery, NOS to Locoregional Site.

Follow-up (4 entries)
- Day 23 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Days to progression: 23 days.
- Day 110 (post initial treatment): Progression or recurrence: Yes.
- Days to follow up: 162 days; Disease response: With Tumor.
- Days to follow up: 162 days; Disease response: Tumor Free.

Molecular and laboratory tests
- Calcium: Low.
- Hemoglobin: Normal.
- Leukocytes: Normal.
- Platelets: Normal.

Exposures
- Exposure type: Tobacco.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-BP-4771-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.3; Intermediate dimension: 0.8; Shortest dimension: 0.1.
  Slide TCGA-BP-4771-01A-01-BS1: Section location: Bottom; Percent tumor cells: 95; Percent tumor nuclei: 90; Percent necrosis: 5; Percent lymphocyte infiltration: 5.
  Slide TCGA-BP-4771-01A-01-TS1: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 90; Percent necrosis: 5; Percent lymphocyte infiltration: 5.
- Sample TCGA-BP-4771-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-BP-4771-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 1.7; Intermediate dimension: 0.8; Shortest dimension: 0.2.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Kidney Clear Cell Renal Carcinoma; History neoadjuvant treatment: Yes; Prospective collection: No; Retrospective collection: Yes; Tumor status: Tumor free; Serum calcium level: Low; Lymph nodes examined: Yes.
- Radiation treatment 1: Radiation type other: Intensity-Modulated radiation therapy; Therapy regimen: Recurrence.
- Radiation treatment 2: Therapy regimen: OTHER, SPECIFY IN NOTES.
- Follow-up form 1: New tumor event surgery: No; Tumor status: With tumor; New tumor event pharmaceutical treatment: No; New tumor event surgery met: No.
- Follow-up form 2: New tumor event surgery: No; Tumor status: With tumor; New tumor event radiation treatment: Yes; New tumor event pharmaceutical treatment: No; New tumor event surgery met: Yes.
- Follow-up form 3: New tumor event surgery: No; Tumor status: With tumor; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: No; New tumor event surgery met: No.

GDC annotations on this case (curator notes; quoted as recorded):
- Neoadjuvant therapy: Per the TSS, the patient had prior chemotherapy (but no additional info given). Also the patient had radiation (external beam) 2 months prior to the TCGA cancer procurement.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 162 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 162 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 23 days.
